Somatic mutation profile of tumor specimen 0DSI9U from CCDI case PBCICF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 13.3 years (4,864 days).
Specimen 0DSI9U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf443ca6-5148-46bc-a1eb-faeeb203948b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI87 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cfbb40a-0241-4a82-8d40-d0d36e04d2e0

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Silent 1, Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACE2 | c.1741G>A p.V581I | Missense Mutation (SNP) | VAF 134/1235 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.343); catalogued as COSV53024143; called by muse, mutect2, varscan2
- NF2 | c.588_592dup p.R198Qfs*13 | Frame Shift Ins (INS) | VAF 262/434 reads (60%) | called by mutect2, varscan2
- RFESD | c.393G>A p.V131= | Silent (SNP) | VAF 293/783 reads (37%) | called by muse, mutect2, varscan2
- CCDC66 | c.711-65T>G | Intron (SNP) | VAF 38/353 reads (11%) | called by muse, mutect2
